Surgical pathology report (de-identified scan), TCGA case TCGA-UE-A6QT, project TCGA-SARC (Sarcoma), tissue source site  Asterand, specimen TCGA-UE-A6QT-01A (Primary Tumor).

[page 1 of 2]
Patient ID:

Surgical Date:

Gross Description: In Soft tissue, Neck and back, There is a lobulated mass. They are encapsulated, with 15x8x6cm in size, solid, yellow and gray surface.

Microscopic Description: Tumor is heterogenous and composed of sheets or trabeculae or bundles. The majority of cell tumours are spindle. Tumour is moderate cellularity. Tumour has in marked cytological and nuclear pleomorphism, with spindle or oval in shape. Cytoplasm are basophilic and scant and vasculature containing lipid. Nuclei are hyperchromatic and very irregular with prominent nucleoli. Mitosis are present. Tumor is invasion of skeletal muscle.

Diagnosis Details: Pleomorphic Liposarcoma

Comments:

Formatted Path Reports: Tumor site: Soft tissue, upper back

Tumor size (in cm): 15 x 8 x 6cm

Histologic type: Pleomorphic Liposarcoma

Histologic grade: Poorly differentiated

Tumor extent: Tumor is invades skeletal muscle.

Lymph nodes:

Margins:

Evidence of neo-adjuvant treatment:

If yes, type of treatment seen:

Severity of treatment effect:

Comments:

ICD-O-3

Liposarcoma, pleomorphic
8854/3

Date ^{CCLF} Head and neck NOS
path Soft tissue of back C49.0
7/5/13

W 11/7/13

Diagnosis Discrepancy	Path is form ✓	

[page 2 of 2]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name) _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	De-differentiated liposarcoma.	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Pleomorphic - liposarcoma	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Slides:	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file bcef118e-f236-4ab6-b166-ec781bf9df40 (TCGA-UE-A6QT.C916B36E-3787-49A9-9DEB-E8F09F646055.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).